Somatic mutation profile of tumor specimen TCGA-DD-A73A-01A (aliquot TCGA-DD-A73A-01A-12D-A32G-10) from TCGA case TCGA-DD-A73A, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 71.6 years (26,136 days).
Specimen TCGA-DD-A73A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7172a5ad-25e7-4a89-8dc0-1a7bbd12ee08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A73A-10A (Blood Derived Normal), aliquot TCGA-DD-A73A-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8908b65-a8f9-41b7-9907-65b11f9f4aa3

The open-access MAF lists 114 somatic variants for this specimen: 87 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 75, Silent 27, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1160A>T p.N387I | Missense Mutation (SNP) | VAF 44/144 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62719838; called by muse, mutect2, varscan2
- AC006059.2 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV59609520; called by muse, mutect2, varscan2
- ACOT12 | c.1663T>G p.F555V | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV56898136; called by muse, mutect2, varscan2
- ADAMTS13 | c.2261G>A p.C754Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100747229; called by muse, mutect2
- ADGRV1 | c.1501C>A p.P501T | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67995429; called by muse, mutect2, varscan2
- ANKRD27 | c.1921T>C p.S641P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.36); catalogued as COSV60135995; called by muse, mutect2
- ANO6 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.166); catalogued as COSV57667918; called by muse, mutect2, varscan2
- ASPH | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 92/303 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as COSV62861402; called by muse, mutect2, varscan2
- CELA3B | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 125/386 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61405697; called by muse, mutect2, varscan2
- CNOT2 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV57507031; called by muse, mutect2, varscan2
- COL6A6 | c.5383C>A p.P1795T | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV62037503; called by muse, mutect2, varscan2
- CPSF3 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53011919; called by muse, mutect2, varscan2
- CYP11B2 | c.741G>T p.W247C | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV59997850; called by muse, mutect2, varscan2
- CYP11B2 | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV59997857; called by muse, mutect2, varscan2
- DDX50 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.669); catalogued as rs753786385, COSV65293345; called by muse, mutect2, varscan2
- DENND2B | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58207771; called by muse, mutect2, varscan2
- DESI2 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV55643156; called by muse, mutect2, varscan2
- DOCK8 | c.2995C>G p.H999D | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs745843220, COSV66623959; called by muse, mutect2, varscan2
- EGFR | c.1232C>G p.P411R | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51846765; called by muse, mutect2, varscan2
- FAM189B | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1300944087; called by muse, mutect2
- FANCB | c.1105-1G>A p.X369_splice | Splice Site (SNP) | VAF 88/122 reads (72%) | catalogued as COSV60761807; called by muse, mutect2, varscan2
- FAT2 | c.12364G>T p.A4122S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV55829309; called by muse, mutect2
- FIZ1 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs777883921, COSV55609270; called by muse, mutect2, varscan2
- FRAS1 | c.1887dup p.K630Qfs*19 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs776570778; called by mutect2, varscan2
- GOLM2 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.925); catalogued as COSV55466430; called by muse, mutect2, varscan2
- GPR61 | c.1180T>C p.S394P | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63984531; called by muse, mutect2, varscan2
- HDLBP | c.1128C>G p.H376Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60500848; called by muse, mutect2, varscan2
- IGF1R | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143193096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS13 | c.1521A>C p.K507N | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV53905553; called by muse, mutect2, varscan2
- IRX1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57362444; called by muse, mutect2, varscan2
- JAKMIP3 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as COSV53829264; called by muse, mutect2, varscan2
- KATNA1 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59503988; called by muse, mutect2, varscan2
- KLF10 | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1307576689, COSV53436845; called by muse, mutect2, varscan2
- KLHDC4 | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54511289; called by muse, mutect2, varscan2
- LAMC2 | c.310T>A p.C104S | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV51459749; called by muse, mutect2, varscan2
- LARP1 | c.1173C>G p.S391R (on ENST00000518297 / NM_033551.3; = p.S314R on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV60431377; called by muse, mutect2, varscan2
- LIPH | c.958A>T p.T320S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56186259; called by muse, mutect2, varscan2
- LY96 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 115/367 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53026881; called by muse, mutect2, varscan2
- MAN2A1 | c.1770T>G p.H590Q | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV99811952; called by muse, mutect2
- MAP1S | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.147); catalogued as COSV60724643; called by muse, mutect2, varscan2
- MEX3C | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV68530616; called by muse, mutect2, varscan2
- MGAT5 | c.2183A>T p.D728V | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56101204; called by muse, mutect2, varscan2
- MSL3 | c.949C>A p.P317T (on ENST00000312196 / NM_078629.4; = p.P151T on NM_006800.4) | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56496130; called by muse, mutect2, varscan2
- MYO15A | c.2911G>T p.V971L | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV52766068; called by muse, mutect2, varscan2
- NACC2 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV53201356; called by muse, mutect2, varscan2
- NEK2 | c.1111+2T>A p.X371_splice | Splice Site (SNP) | VAF 64/230 reads (28%) | catalogued as COSV65357369; called by muse, mutect2, varscan2
- NIBAN1 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV62287692; called by muse, mutect2, varscan2
- NLGN4X | c.2333C>T p.T778I | Missense Mutation (SNP) | VAF 72/136 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV52032832; called by muse, mutect2, varscan2
- OPA3 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55607424, COSV55608167; called by muse, mutect2, varscan2
- OR10H1 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.369); catalogued as COSV58470548, COSV58473068; called by muse, mutect2, varscan2
- OR2L8 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs749883227, COSV61726105, COSV61728344; called by muse, mutect2, varscan2
- OSR2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1284390401, COSV52559051; called by muse, mutect2, varscan2
- PAM | c.2642T>A p.L881Q | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57219920; called by muse, mutect2, varscan2
- PATL1 | c.1705T>G p.L569V | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55690431; called by muse, mutect2, varscan2
- PCDH10 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV52103864; called by muse, mutect2
- PCDH15 | c.5233T>C p.S1745P | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated, low confidence (0.22); catalogued as COSV64737551; called by muse, mutect2, varscan2
- PCDHB10 | c.2246A>T p.Q749L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.501); catalogued as COSV53383826; called by muse, mutect2, varscan2
- PCDHGA12 | c.1415T>A p.V472D | Missense Mutation (SNP) | VAF 101/219 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as COSV52768245; called by muse, mutect2, varscan2
- PDHB | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV57058012; called by muse, mutect2, varscan2
- PLCD4 | c.1875A>C p.K625N | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV68745676; called by muse, mutect2, varscan2
- PPP2R3A | c.3256T>A p.W1086R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53870721; called by muse, mutect2, varscan2
- PRAMEF6 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as rs780227408, COSV100755929; called by muse, varscan2
- PRKN | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as rs373750972, CM080475; called by muse, mutect2, varscan2
- PUM1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.155); catalogued as COSV57091305; called by muse, mutect2, varscan2
- RBBP8NL | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV53351099; called by muse, mutect2, varscan2
- SCD5 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751126623, COSV51104739; called by muse, mutect2, varscan2
- SGO2 | c.309G>C p.L103F | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63418073; called by muse, mutect2, varscan2
- SLC25A29 | c.728G>A p.G243D (on ENST00000359232 / NM_001039355.3; = p.G177D on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172983563, COSV63651650; called by muse, mutect2, varscan2
- SLFN11 | c.2323G>T p.G775* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV57700539; called by muse, mutect2, varscan2
- SLIT2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333523681, COSV56588499; called by muse, mutect2, varscan2
- SYCP2 | c.3413C>T p.S1138L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs755198324, COSV62772554; called by muse, mutect2, varscan2
- TRPS1 | c.163A>C p.N55H (on ENST00000220888 / NM_001330599.2; = p.N68H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/204 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV55262067; called by muse, mutect2, varscan2
- UMPS | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs749083040, COSV51739130; called by muse, mutect2, varscan2
- VAT1L | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56828756; called by muse, mutect2, varscan2
- WDR46 | c.1069T>A p.C357S | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as COSV65842964; called by muse, mutect2, varscan2
- XPO7 | c.1334A>T p.Q445L | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV53020453; called by muse, mutect2, varscan2
- ZMYM4 | c.1889A>G p.Q630R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1008248421, COSV58917165; called by muse, mutect2, varscan2
- ZNF18 | c.982T>G p.F328V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs765856443, COSV59551113; called by muse, mutect2, varscan2
- ZNF552 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs753669522, COSV66971953; called by muse, mutect2, varscan2
- CCL3 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FGA | c.1124_1126dup p.S375_E376insA | In Frame Ins (INS) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.314_330del p.I105Nfs*3 | Frame Shift Del (DEL) | VAF 42/253 reads (17%) | called by pindel, varscan2
- PLPPR4 | c.1587del p.S530Pfs*15 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- THADA | c.1310_1311dup p.V438Lfs*4 | Frame Shift Ins (INS) | VAF 29/94 reads (31%) | called by mutect2, pindel, varscan2
- TPTE | c.1611del p.F537Lfs*5 (on ENST00000618007 / NM_199261.4; = p.F519Lfs*5 on NM_199259.4) | Frame Shift Del (DEL) | VAF 38/332 reads (11%) | called by mutect2, pindel, varscan2
- TRAIP | c.1362_1363del p.V455Afs*31 | Frame Shift Del (DEL) | VAF 71/217 reads (33%) | called by mutect2, pindel, varscan2
- VWF | c.2499_2505del p.K834Mfs*7 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- ADAM29 | c.1276C>T p.L426= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV63668175; called by muse, mutect2, varscan2
- CDH11 | c.1794C>T p.N598= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs563299959, COSV51764281, COSV51767424; called by muse, mutect2, varscan2
- CENPJ | c.2997A>G p.L999= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV67884262; called by muse, mutect2, varscan2
- CEP162 | c.744T>A p.S248= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV57624698; called by muse, mutect2, varscan2
- COG1 | c.2349C>T p.A783= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as COSV55431968; called by muse, mutect2, varscan2
- COL3A1 | c.873C>T p.G291= | Silent (SNP) | VAF 70/242 reads (29%) | catalogued as rs138569287, COSV58598296; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ERC2 | c.405C>A p.V135= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as rs141688594, COSV55609957, COSV55663960; called by muse, mutect2, varscan2
- FMNL1 | c.1821G>A p.P607= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100056970; called by muse, mutect2
- GNGT2 | c.174T>C p.N58= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as COSV55930328; called by muse, mutect2, varscan2
- KIAA1109 | c.306A>C p.G102= | Silent (SNP) | VAF 38/230 reads (17%) | called by muse, varscan2
- MAP1B | c.4008C>T p.Y1336= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs771081682, COSV57106386; called by muse, mutect2, varscan2
- MAP3K12 | c.2505A>T p.S835= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as COSV57236039; called by muse, mutect2, varscan2
- MMRN1 | c.1389T>C p.I463= | Silent (SNP) | VAF 94/261 reads (36%) | catalogued as COSV53342732; called by muse, mutect2, varscan2
- MTMR6 | c.1413T>A p.P471= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV67809839; called by muse, mutect2, varscan2
- NIPBL | c.4299T>C p.C1433= | Silent (SNP) | VAF 75/229 reads (33%) | catalogued as COSV56966044; called by muse, mutect2, varscan2
- NOS1 | c.2280G>C p.A760= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV57619313, COSV57621883; called by muse, mutect2, varscan2
- PAK6 | c.1071C>T p.A357= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV53048020; called by muse, mutect2
- PCK2 | c.540C>T p.D180= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV53750673; called by muse, mutect2, varscan2
- POU4F2 | c.1035G>A p.K345= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV55586728; called by muse, mutect2, varscan2
- R3HDM2 | c.2046T>A p.S682= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV61295347; called by muse, mutect2, varscan2
- RRP9 | c.858G>A p.V286= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV51756590; called by muse, mutect2, varscan2
- SGK1 | c.312C>T p.I104= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as rs1015971626, COSV52806102; called by muse, mutect2, varscan2
- SLCO3A1 | c.582G>T p.V194= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV59237416; called by muse, mutect2, varscan2
- TNRC6A | c.3933C>A p.A1311= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as COSV59370178; called by muse, mutect2, varscan2
- TPTE | c.1608T>A p.L536= (on ENST00000618007 / NM_199261.4; = p.L518= on NM_199259.4) | Silent (SNP) | VAF 38/309 reads (12%) | called by mutect2, varscan2
- USP16 | c.738A>G p.P246= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV57627958; called by muse, mutect2, varscan2
- WWP2 | c.2451A>G p.G817= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV63127824; called by muse, mutect2, varscan2
